Somatic mutation profile of tumor specimen TCGA-DD-AACI-01A (aliquot TCGA-DD-AACI-01A-11D-A40R-10) from TCGA case TCGA-DD-AACI, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 69.1 years (25,236 days).
Specimen TCGA-DD-AACI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1c07af7-a6f5-475d-ae11-bea4d755dbbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACI-10A (Blood Derived Normal), aliquot TCGA-DD-AACI-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dabae4b-9c98-43d9-9f65-67e2996fa2e2

The open-access MAF lists 413 somatic variants for this specimen: 303 protein-altering or splice-affecting, 100 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 100, Nonsense Mutation 18, Splice Site 9, Frame Shift Del 8, Intron 6, Splice Region 4, Frame Shift Ins 2, RNA 1, In Frame Ins 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS12 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1450190654, CM070034, COSV100044896; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2300_2308dup p.A767_V769dup | In Frame Ins (INS) | VAF 24/139 reads (17%) | hotspot (GDC flag); catalogued as rs727504263; ClinVar: drug response; called by mutect2, varscan2
- ABCA3 | c.1864A>G p.T622A | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100068284; called by muse, mutect2, varscan2
- ACBD3 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 103/172 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100830969; called by muse, mutect2, varscan2
- ACSL3 | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100657910; called by muse, mutect2, varscan2
- ACSS3 | c.1889T>A p.V630E | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99698563; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1216A>G p.K406E | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.174); catalogued as COSV99835976; called by muse, mutect2, varscan2
- ADCY9 | c.3868A>G p.K1290E | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99569722; called by muse, mutect2, varscan2
- ADGRL4 | c.1706A>T p.N569I | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100875826; called by muse, mutect2, varscan2
- AHNAK2 | c.7396G>A p.E2466K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV100316858; called by muse, mutect2, varscan2
- ALDH1A3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 17/90 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV60901879; called by muse, mutect2, varscan2
- ALDH7A1 | c.865A>T p.R289W | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101302000, COSV68629151; called by muse, mutect2, varscan2
- ALG5 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99523585; called by muse, mutect2, varscan2
- ALOX15B | c.653A>T p.N218I | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV101205596; called by muse, mutect2, varscan2
- AMER2 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs866338607, COSV100766200; called by muse, mutect2, varscan2
- ANKRD52 | c.1512A>G p.R504= | Splice Region (SNP) | VAF 12/87 reads (14%) | catalogued as COSV99921207; called by muse, mutect2, varscan2
- ANKS1A | c.2917G>C p.E973Q | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100832253; called by muse, mutect2, varscan2
- ANKS1B | c.1334C>A p.T445K | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV101612661; called by muse, mutect2, varscan2
- AQR | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99333683; called by muse, varscan2
- ARHGAP20 | c.2521A>G p.T841A | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99503651; called by muse, mutect2, varscan2
- ATP2B1 | c.1093A>T p.K365* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99665453; called by muse, mutect2, varscan2
- B3GNT6 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs782053863, COSV100845771; called by muse, mutect2, varscan2
- B4GALNT3 | c.2732A>T p.H911L | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV99842781; called by muse, mutect2, varscan2
- BAHCC1 | c.4898G>A p.R1633Q | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.755); catalogued as rs781853812, COSV100311446; called by muse, mutect2, varscan2
- BIRC7 | c.373T>A p.F125I | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99416602; called by muse, mutect2, varscan2
- BTD | c.1049A>G p.Y350C | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs148193489; called by muse, mutect2, varscan2
- C10orf90 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs757878412, COSV52950145; called by muse, mutect2, varscan2
- C14orf39 | c.1241G>C p.R414T | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs759940478, COSV100407437; called by muse, mutect2, varscan2
- C5 | c.838A>T p.K280* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99797595; called by muse, mutect2, varscan2
- C5orf15 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV99198309; called by muse, mutect2, varscan2
- C9 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs764410729, COSV54678927, COSV54680338; called by muse, mutect2, varscan2
- C9orf131 | c.865A>T p.R289W | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV100398017; called by muse, mutect2, varscan2
- CACNA1E | c.6707A>G p.H2236R (on ENST00000367573 / NM_001205293.3; = p.H2193R on NM_000721.4) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs781574328, COSV100701941; called by muse, mutect2
- CAND1 | c.967A>G p.M323V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs1323687794, COSV101598267; called by muse, mutect2, varscan2
- CCDC114 | c.1054A>T p.K352* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100196590; called by muse, mutect2, varscan2
- CCDC130 | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.129); catalogued as COSV99237366; called by muse, mutect2, varscan2
- CCDC138 | c.267-2A>T p.X89_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | catalogued as COSV99718999; called by muse, mutect2, varscan2
- CCDC144A | c.3000G>C p.L1000F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as COSV100138480; called by mutect2, varscan2
- CD151 | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV100431749; called by muse, mutect2, varscan2
- CD300LF | c.500T>A p.L167Q | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100042722; called by muse, mutect2, varscan2
- CDC25B | c.478A>T p.S160C (on ENST00000245960 / NM_021873.3; = p.S146C on NM_004358.4) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99847800; called by muse, mutect2, varscan2
- CDH18 | c.977A>G p.E326G | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99933613; called by muse, mutect2, varscan2
- CDH23 | c.5650G>A p.A1884T | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as rs1277608253, COSV99820169; called by muse, mutect2, varscan2
- CDK11B | c.2033A>T p.E678V | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV100477563; called by muse, mutect2, varscan2
- CENPE | c.4786A>T p.K1596* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99477543; called by muse, mutect2, varscan2
- CEP95 | c.2241A>G p.I747M | Missense Mutation (SNP) | VAF 105/408 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV101616307; called by muse, mutect2, varscan2
- CHCHD10 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100533606; called by muse, mutect2
- CHRM3 | c.1621C>G p.P541A | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698009; called by muse, mutect2
- CIITA | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.171); catalogued as COSV100161333, COSV100161716; called by muse, mutect2, varscan2
- CIR1 | c.1261A>T p.S421C | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV100564931; called by muse, mutect2, varscan2
- CLCN7 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.727); catalogued as COSV99247111; called by muse, mutect2, varscan2
- CMYA5 | c.1165A>G p.M389V | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101483977; called by muse, mutect2, varscan2
- COMMD5 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100295788; called by muse, mutect2, varscan2
- CORO7 | c.2773-2A>T p.X925_splice | Splice Site (SNP) | VAF 22/149 reads (15%) | catalogued as COSV99227467; called by muse, mutect2, varscan2
- CPEB4 | c.1447A>G p.I483V | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.782); catalogued as COSV99436943; called by muse, mutect2, varscan2
- CREB3L3 | c.976-2A>G p.X326_splice | Splice Site (SNP) | VAF 26/64 reads (41%) | catalogued as COSV99313995, COSV99314206; called by muse, mutect2, varscan2
- CRNN | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV99664066; called by muse, mutect2, varscan2
- CUL9 | c.5698G>T p.A1900S | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as COSV99335175; called by muse, mutect2
- CYB561 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314390526, COSV100669094; called by muse, mutect2, varscan2
- CYP27C1 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100079775; called by muse, mutect2, varscan2
- CYTH1 | c.15C>G p.D5E | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100739250; called by muse, mutect2, varscan2
- DCAF12L2 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100758533; called by muse, mutect2, varscan2
- DDC | c.877-2A>T p.X293_splice | Splice Site (SNP) | VAF 16/106 reads (15%) | catalogued as COSV63565519; called by muse, mutect2, varscan2
- DENND3 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.058); catalogued as rs531863353, COSV99370737; called by muse, mutect2, varscan2
- DGKE | c.1322T>A p.L441* | Nonsense Mutation (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99400844; called by muse, mutect2, varscan2
- DHX9 | c.70A>G p.R24G | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100841342; called by muse, mutect2
- DHX9 | c.977A>G p.Q326R | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV100841344; called by muse, mutect2
- DICER1 | c.2256A>T p.A752= | Splice Region (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100601969; called by muse, mutect2, varscan2
- DLX5 | c.812T>A p.L271Q | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99756367; called by muse, mutect2, varscan2
- DOCK3 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as COSV99810769; called by muse, mutect2, varscan2
- DSG4 | c.1117A>T p.R373* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as COSV100355671; called by muse, mutect2, varscan2
- E2F1 | c.623A>T p.Q208L | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV99864642; called by muse, mutect2, varscan2
- ENPP1 | c.1195A>T p.M399L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100719482; called by muse, mutect2, varscan2
- EPHB2 | c.2426T>C p.V809A (on ENST00000400191 / NM_001309193.2; = p.V810A on NM_004442.7) | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as rs759393577, COSV101006887; called by muse, mutect2, varscan2
- ESPN | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 259/675 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100911387; called by muse, mutect2, varscan2
- ESR1 | c.1451A>G p.D484G | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99238612; called by muse, mutect2, varscan2
- FAM13C | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV99513485; called by muse, mutect2, varscan2
- FAM13C | c.250A>G p.M84V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as COSV99513488; called by muse, mutect2, varscan2
- FAM160B1 | c.1760A>G p.E587G | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100985384; called by muse, mutect2, varscan2
- FAT2 | c.5532C>A p.D1844E | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99942362; called by muse, mutect2, varscan2
- FBLN2 | c.1885T>A p.C629S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55488263; called by muse, mutect2, varscan2
- FHL1 | c.853A>G p.R285G | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV100600739; called by muse, mutect2, varscan2
- FLNC | c.3990T>A p.Y1330* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100367896; called by muse, mutect2, varscan2
- FLNC | c.7574A>T p.E2525V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as COSV100367898; called by muse, mutect2, varscan2
- GBX1 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99880852; called by muse, mutect2, varscan2
- GIMAP2 | c.440A>T p.H147L | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV99785295; called by muse, mutect2, varscan2
- GIMAP6 | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.071); catalogued as COSV100188180; called by muse, mutect2, varscan2
- GIN1 | c.1276A>T p.R426* | Nonsense Mutation (SNP) | VAF 19/117 reads (16%) | catalogued as COSV101204301; called by muse, mutect2, varscan2
- GPHN | c.1573A>T p.S525C (on ENST00000315266 / NM_001377519.1; = p.S558C on NM_020806.5) | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100015886; called by muse, mutect2, varscan2
- GRIN3B | c.894A>T p.Q298H | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99312380; called by muse, mutect2
- GRM2 | c.805T>A p.F269I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99622678; called by muse, mutect2, varscan2
- GRM5 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100551242; called by muse, mutect2, varscan2
- GYS2 | c.1570A>G p.I524V | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.961); catalogued as COSV99679648; called by muse, mutect2, varscan2
- H6PD | c.1937T>A p.I646N | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV101072444; called by muse, mutect2
- HLCS | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs1167581539, COSV100358086; called by muse, mutect2, varscan2
- HMCN1 | c.5374A>G p.I1792V | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV99627287; called by muse, mutect2, varscan2
- HNF4A | c.1415A>T p.E472V | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV100291288; called by muse, mutect2, varscan2
- HOXD12 | c.734A>T p.Q245L | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101184210; called by muse, mutect2, varscan2
- IFIT2 | c.766T>A p.F256I | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99260131; called by muse, mutect2, varscan2
- IFNAR2 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.05); catalogued as COSV100577089; called by muse, mutect2, varscan2
- IL1R1 | c.862A>G p.R288G | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV99292514; called by muse, mutect2, varscan2
- IL5 | c.93A>T p.K31N | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.22); catalogued as COSV99185046; called by muse, mutect2, varscan2
- INPP5E | c.1901G>C p.S634T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100867222; called by muse, mutect2, varscan2
- INSYN2A | c.17C>A p.T6N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV99728562; called by muse, mutect2
- IQGAP3 | c.4793A>T p.Q1598L | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100752112; called by muse, mutect2
- IREB2 | c.962A>T p.E321V | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV99359267; called by muse, mutect2, varscan2
- IRS4 | c.3674C>A p.P1225H | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.831); catalogued as rs752900509, COSV100929508; called by muse, mutect2, varscan2
- ISG20L2 | c.50A>T p.K17M | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100493966; called by muse, mutect2, varscan2
- ITGAX | c.1381T>A p.S461T | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.918); catalogued as COSV99191586; called by muse, mutect2, varscan2
- KCNK13 | c.625T>C p.S209P | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99965606; called by muse, mutect2, varscan2
- KCNN3 | c.1334T>C p.F445S | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV99678063; called by muse, mutect2
- KCNU1 | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101299112; called by muse, mutect2, varscan2
- KIF24 | c.317A>T p.N106I | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100799143; called by muse, mutect2, varscan2
- KIF5C | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV101371334; called by muse, mutect2, varscan2
- KIRREL1 | c.2050T>A p.Y684N | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV100779685; called by muse, mutect2
- KLF16 | c.724A>T p.S242C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99170518; called by muse, mutect2, varscan2
- KLF8 | c.647T>A p.V216E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100808197; called by muse, mutect2, varscan2
- KMT2A | c.4366C>T p.H1456Y | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100628508, COSV63287492; called by muse, mutect2, varscan2
- KRT76 | c.1517T>C p.I506T | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100196093; called by muse, mutect2, varscan2
- KRT85 | c.352T>C p.C118R | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99225317; called by muse, mutect2, varscan2
- KRTAP17-1 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | PolyPhen benign (0.094); catalogued as rs1168833563, COSV61972233; called by muse, mutect2, varscan2
- LAX1 | c.88A>T p.R30* | Nonsense Mutation (SNP) | VAF 20/202 reads (10%) | catalogued as COSV100920026; called by muse, mutect2, varscan2
- LEO1 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100166469; called by muse, mutect2, varscan2
- LIMS2 | c.331G>T p.D111Y (on ENST00000355119 / NM_001161403.3; = p.D135Y on NM_017980.4) | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99760517; called by muse, mutect2, varscan2
- LIX1 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs758887825, COSV99172872; called by muse, mutect2, varscan2
- LMOD1 | c.47A>T p.D16V | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100939125; called by muse, mutect2
- LRRC71 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.352); catalogued as rs1290811030, COSV100168458; called by muse, mutect2, varscan2
- LRRFIP2 | c.1036-2A>G p.X346_splice | Splice Site (SNP) | VAF 8/94 reads (9%) | catalogued as COSV100368309; called by muse, mutect2
- LSM1 | c.97A>G p.R33G | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99781779; called by muse, mutect2, varscan2
- LTBP2 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs371940681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAN1A1 | c.566A>T p.D189V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV100870349; called by muse, mutect2, varscan2
- MAP1LC3A | c.140T>A p.L47Q | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99466242; called by muse, mutect2, varscan2
- MAP7 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs770364619, COSV100643822; called by muse, mutect2, varscan2
- MAP9 | c.595A>T p.T199S | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as COSV100250841; called by muse, mutect2, varscan2
- MATN2 | c.1895A>C p.K632T | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.316); catalogued as COSV99646060; called by muse, mutect2, varscan2
- MCC | c.2340G>C p.K780N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56728001; called by muse, mutect2, varscan2
- MGAM | c.1997C>A p.P666H | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV101527441, COSV72073576; called by muse, mutect2, varscan2
- MPRIP | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 52/274 reads (19%) | catalogued as COSV100505429; called by muse, mutect2, varscan2
- MS4A12 | c.117A>T p.L39F | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.154); catalogued as COSV99188662; called by muse, mutect2
- MUC16 | c.43190C>T p.P14397L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV101109799; called by muse, mutect2, varscan2
- MUC17 | c.5854G>A p.D1952N | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.665); catalogued as COSV100072649; called by muse, mutect2, varscan2
- MUC6 | c.929A>T p.E310V | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101424503; called by muse, mutect2, varscan2
- MYH14 | c.1448A>T p.E483V | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99222330; called by muse, mutect2
- MYH6 | c.3554T>A p.L1185Q | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100676433; called by muse, mutect2, varscan2
- MYH7 | c.4861G>T p.D1621Y | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100805940; called by muse, mutect2, varscan2
- MYLK2 | c.344A>T p.Q115L | Missense Mutation (SNP) | VAF 296/1528 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV101044735; called by muse, mutect2, varscan2
- NDUFS2 | c.938A>T p.Q313L | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99248178; called by muse, mutect2
- NFXL1 | c.998A>T p.Q333L | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100216710; called by muse, mutect2, varscan2
- NID1 | c.988A>T p.S330C | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV99937325; called by muse, mutect2, varscan2
- NID2 | c.2722T>A p.Y908N | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV99356287; called by muse, mutect2, varscan2
- NKAPL | c.500G>T p.S167I | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100642487; called by muse, mutect2, varscan2
- NPAS4 | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100214921; called by muse, mutect2, varscan2
- NPR3 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54088236; called by muse, mutect2, varscan2
- NR5A1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs988948243, CM118939, COSV101007676; called by muse, mutect2, varscan2
- NTM | c.401-2A>T p.X134_splice | Splice Site (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100868147, COSV66196181; called by muse, mutect2, varscan2
- NTN1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as rs777691583, COSV99432721; called by muse, mutect2, varscan2
- NUP155 | c.98A>G p.Q33R | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as COSV99192581; called by muse, mutect2, varscan2
- NUP214 | c.2142G>T p.Q714H | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845224, COSV63910409; called by muse, mutect2, varscan2
- OOSP2 | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99613335; called by muse, mutect2
- OR13C5 | c.950A>T p.N317I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV101053079; called by muse, mutect2, varscan2
- OR1C1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.145); catalogued as COSV101376212, COSV68716464; called by muse, mutect2
- OR2AK2 | c.209A>C p.D70A | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100823391; called by muse, mutect2, varscan2
- OR2J2 | c.197A>C p.N66T | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV101013332; called by muse, mutect2, varscan2
- OR2T12 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 80/930 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100527678; called by muse, mutect2
- OR4K15 | c.115C>A p.L39M (on ENST00000305051; = p.L15M on NM_001005486.1) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100521019; called by muse, mutect2, varscan2
- OR56B1 | c.220A>T p.I74F | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV100402587; called by muse, mutect2, varscan2
- OTUD3 | c.493A>T p.T165S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.03); catalogued as COSV100909010; called by muse, mutect2, varscan2
- PABPC1L | c.1725G>C p.M575I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV99407706; called by muse, mutect2
- PATJ | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 43/118 reads (36%) | catalogued as rs200079447, COSV57157558; called by muse, mutect2, varscan2
- PCDHA12 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99165601; called by muse, mutect2
- PCDHB12 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV99507091; called by muse, mutect2, varscan2
- PCDHB16 | c.647A>T p.D216V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99501710; called by muse, mutect2, varscan2
- PCLO | c.7648G>T p.A2550S | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.085); catalogued as COSV100430367; called by muse, mutect2, varscan2
- PCLO | c.3579A>T p.Q1193H | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs765390976, COSV100430370; called by muse, mutect2, varscan2
- PCLO | c.2537T>A p.V846D | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100430371; called by muse, mutect2
- PDE6B | c.1833-2A>T p.X611_splice | Splice Site (SNP) | VAF 11/115 reads (10%) | catalogued as COSV55328758; called by muse, mutect2
- PGLYRP2 | c.889A>T p.S297C | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99483924; called by muse, mutect2
- PHC2 | c.2324A>G p.H775R (on ENST00000257118 / NM_198040.2; = p.H240R on NM_004427.4) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as rs1414711138, COSV99930909; called by muse, mutect2, varscan2
- PHEX | c.1679T>C p.F560S | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101039546; called by muse, mutect2, varscan2
- PHF24 | c.1094A>T p.E365V | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.122); catalogued as rs1351388142, COSV99646008; called by muse, mutect2, varscan2
- PIK3C2G | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs748292087, COSV99850852; called by muse, mutect2
- PITPNM2 | c.2896A>T p.N966Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.613); catalogued as COSV99758641; called by muse, mutect2, varscan2
- PKN2 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 130/324 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV60130188; called by muse, mutect2
- PMPCB | c.516A>T p.E172D | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV99971205; called by muse, mutect2
- PNISR | c.1124A>T p.Q375L | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV100984335; called by muse, mutect2, varscan2
- PNISR | c.902A>G p.E301G | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100984336; called by muse, mutect2, varscan2
- PPARGC1A | c.766A>G p.T256A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as rs1466813726, COSV99337706; called by muse, mutect2, varscan2
- PPHLN1 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV99871701; called by muse, mutect2, varscan2
- PRDX6 | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100458457; called by muse, mutect2
- PREX1 | c.397A>T p.N133Y | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV100906169; called by muse, mutect2
- PROM2 | c.1050+1G>T p.X350_splice | Splice Site (SNP) | VAF 24/55 reads (44%) | catalogued as COSV100468864; called by muse, mutect2, varscan2
- PRUNE2 | c.6457T>C p.F2153L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100944416; called by muse, mutect2, varscan2
- PTCD2 | c.182A>G p.K61R | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.355); catalogued as COSV99782094; called by muse, mutect2, varscan2
- PTPRJ | c.3935A>G p.Q1312R | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101394832; called by muse, mutect2, varscan2
- PTPRN | c.2713A>T p.I905F | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99833871; called by muse, mutect2, varscan2
- RBM41 | c.1018A>T p.I340F | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV99179778; called by muse, mutect2, varscan2
- REC114 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100461241; called by muse, mutect2, varscan2
- REL | c.1075T>C p.Y359H | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as COSV99691996; called by muse, mutect2
- RFC1 | c.2327G>A p.R776Q (on ENST00000381897 / NM_001363496.2; = p.R775Q on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs199688793, COSV100567568; called by muse, mutect2, varscan2
- RFX4 | c.324G>T p.R108S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV99985666; called by muse, mutect2, varscan2
- RHBDF1 | c.1178A>T p.K393M | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV99244472; called by muse, mutect2, varscan2
- RHOJ | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100370195; called by muse, mutect2, varscan2
- RLF | c.1102G>T p.G368C | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101035231; called by muse, mutect2, varscan2
- RNF111 | c.1225G>C p.A409P | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as COSV100788919, COSV100789034; called by mutect2, varscan2
- RSBN1 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.081); catalogued as COSV99793077; called by muse, mutect2, varscan2
- RSL1D1 | c.1118A>G p.K373R | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs758401490, COSV100851961; called by muse, mutect2, varscan2
- RYR3 | c.9179C>T p.A3060V (on ENST00000389232; = p.A3061V on NM_001036.6) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66782678; called by muse, mutect2, varscan2
- SAMD9 | c.4320G>C p.W1440C | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101180182; called by muse, mutect2, varscan2
- SDE2 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99682601; called by muse, mutect2, varscan2
- SEL1L3 | c.827A>T p.E276V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99339931; called by muse, mutect2, varscan2
- SEPTIN6 | c.979A>T p.K327* | Nonsense Mutation (SNP) | VAF 4/76 reads (5%) | catalogued as COSV100595529; called by muse, mutect2
- SERPINA12 | c.587T>C p.I196T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57942841; called by muse, varscan2
- SFRP5 | c.919T>A p.Y307N | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.07); catalogued as rs754037085, COSV99823131; called by muse, mutect2, varscan2
- SGCA | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV100006642; called by muse, mutect2, varscan2
- SGCE | c.101T>G p.L34W | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99722371; called by muse, mutect2, varscan2
- SHANK1 | c.1813T>A p.S605T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99520806; called by muse, mutect2, varscan2
- SLC2A9 | c.1603A>G p.K535E | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as rs747970630, COSV99304365; called by muse, mutect2, varscan2
- SLC44A3 | c.1370A>T p.Y457F (on ENST00000271227 / NM_001114106.3; = p.Y409F on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV99598005; called by muse, mutect2, varscan2
- SLC4A5 | c.1738A>C p.S580R | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100697565; called by muse, mutect2, varscan2
- SLC5A1 | c.268A>C p.T90P | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV99833326; called by muse, mutect2
- SMAD9 | c.175C>A p.L59I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.764); catalogued as COSV100614576, COSV63205303; called by muse, mutect2
- SMOX | c.1271T>A p.L424Q | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99603053; called by muse, mutect2, varscan2
- SNCAIP | c.2009T>G p.L670R | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99748150; called by muse, mutect2
- SORCS3 | c.1171A>C p.I391L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.025); catalogued as COSV100864958; called by muse, mutect2, varscan2
- SOX11 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.483); catalogued as rs1227439657, COSV58983446; called by muse, mutect2
- SP140 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as COSV100613615; called by muse, mutect2, varscan2
- SPAG1 | c.278A>G p.E93G | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV99308720; called by muse, mutect2, varscan2
- SPANXC | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 92/576 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs201591692, COSV62841655; called by muse, mutect2, varscan2
- SPATA21 | c.59T>A p.L20Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.278); catalogued as COSV100130792; called by muse, mutect2, varscan2
- SPSB1 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100049363, COSV60163197; called by muse, mutect2
- SPTA1 | c.5959G>T p.E1987* | Nonsense Mutation (SNP) | VAF 39/389 reads (10%) | catalogued as COSV100934693, COSV63751358; called by muse, mutect2
- SSR1 | c.407A>C p.N136T | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99783661; called by muse, mutect2, varscan2
- ST7 | c.1684A>T p.K562* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV99621599; called by muse, mutect2, varscan2
- STX16 | c.773G>A p.G258E (on ENST00000371141 / NM_001001433.3; = p.G237E on NM_003763.6) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100397361; called by muse, mutect2, varscan2
- STYXL2 | c.2498T>A p.L833Q | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99608930; called by muse, mutect2
- SUCO | c.2533A>T p.I845L | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99742511; called by muse, mutect2
- SUCO | c.3319A>T p.K1107* | Nonsense Mutation (SNP) | VAF 62/667 reads (9%) | catalogued as COSV99742514; called by muse, mutect2
- SYPL1 | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.73); PolyPhen possibly damaging (0.901); catalogued as COSV99163434, COSV99163448; called by muse, mutect2, varscan2
- TANC2 | c.464C>A p.T155K | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.142); catalogued as COSV101267341; called by muse, mutect2, varscan2
- TANC2 | c.2033T>C p.V678A | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761295874, COSV101267343; called by muse, mutect2, varscan2
- TBC1D8 | c.815A>C p.Q272P | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV100964381; called by muse, mutect2, varscan2
- TBX5 | c.1244T>C p.V415A | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100091002; called by muse, mutect2, varscan2
- TG | c.674A>C p.Q225P | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99600124; called by muse, mutect2, varscan2
- THBD | c.1712C>T p.T571M | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs1166732867, COSV101001868; ClinVar: uncertain significance; called by muse, mutect2
- THOC2 | c.3850A>T p.K1284* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as rs1464658220, COSV99833085; called by muse, mutect2
- THOC2 | c.3848A>C p.E1283A | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV99833087; called by muse, mutect2
- TMEFF2 | c.744A>T p.A248= | Splice Region (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99771346; called by muse, mutect2, varscan2
- TMEM163 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV99925988; called by muse, mutect2, varscan2
- TMEM267 | c.626A>T p.H209L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV101230997; called by muse, mutect2, varscan2
- TMTC2 | c.654+2T>A p.X218_splice | Splice Site (SNP) | VAF 13/90 reads (14%) | catalogued as COSV100337742; called by muse, mutect2, varscan2
- TNFRSF1B | c.385A>G p.S129G | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100884147; called by muse, mutect2, varscan2
- TNFSF14 | c.9G>C p.E3D | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV99838416; called by muse, mutect2
- TNR | c.3845A>G p.D1282G | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99688835; called by muse, mutect2, varscan2
- TNR | c.2396C>G p.P799R | Missense Mutation (SNP) | VAF 138/253 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99688837; called by muse, mutect2, varscan2
- TNXB | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100926159; called by muse, mutect2, varscan2
- TOGARAM1 | c.2560A>T p.K854* | Nonsense Mutation (SNP) | VAF 23/127 reads (18%) | catalogued as COSV63894279; called by muse, mutect2, varscan2
- TOGARAM2 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs559495685, COSV101091029; called by muse, mutect2, varscan2
- TOMM22 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99320121; called by muse, mutect2, varscan2
- TRIL | c.1475A>T p.Q492L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100538786; called by muse, mutect2, varscan2
- TRIM7 | c.806A>T p.Q269L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99220127; called by muse, mutect2
- TRPM8 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs200066478, COSV99048831; called by muse, mutect2, varscan2
- TSPOAP1 | c.5408G>T p.G1803V | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV99270704; called by muse, mutect2, varscan2
- TTC19 | c.515A>T p.K172M | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV99890066; called by muse, mutect2, varscan2
- TTN | c.81019C>A p.P27007T (on ENST00000591111; = p.P19583T on NM_003319.4) | Missense Mutation (SNP) | VAF 44/154 reads (29%) | PolyPhen probably damaging (0.999); catalogued as COSV100604568; called by muse, mutect2, varscan2
- TXNDC15 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV100613531; called by muse, mutect2, varscan2
- UPF1 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV99439223; called by muse, mutect2
- USP47 | c.1281A>G p.K427= (on ENST00000399455 / NM_001372095.1; = p.K339= on NM_017944.4 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 18/107 reads (17%) | catalogued as COSV100359388, COSV60465142; called by muse, mutect2, varscan2
- UTP14A | c.1599A>T p.L533F | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV100928949, COSV64086939; called by muse, mutect2, varscan2
- VSIG8 | c.947G>C p.C316S | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.95); catalogued as COSV100928778; called by muse, mutect2, varscan2
- VSIG8 | c.946T>A p.C316S | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.95); catalogued as COSV100928779; called by muse, mutect2, varscan2
- WASF3 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs147802301; called by muse, mutect2, varscan2
- WDR45 | c.217A>T p.K73* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100540206; called by muse, mutect2, varscan2
- WDR5 | c.952T>C p.S318P | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100681830; called by muse, mutect2, varscan2
- WEE2 | c.1220A>T p.E407V | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101187661; called by muse, mutect2, varscan2
- WNK2 | c.797A>T p.K266M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99941816; called by muse, mutect2, varscan2
- WNK2 | c.4078G>A p.A1360T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs769311608, COSV99941820; called by muse, mutect2, varscan2
- XPO1 | c.2542T>G p.F848V | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101294188; called by muse, mutect2, varscan2
- YJU2 | c.553A>T p.R185W | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV99508278; called by muse, mutect2
- ZEB2 | c.2746A>T p.S916C | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV100355675; called by muse, mutect2, varscan2
- ZFC3H1 | c.1448A>G p.E483G | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101110457; called by muse, mutect2, varscan2
- ZFHX3 | c.6275T>C p.M2092T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs1315564329, COSV99196626; called by muse, mutect2, varscan2
- ZFYVE26 | c.2107A>T p.S703C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.428); catalogued as COSV100720287; called by muse, mutect2, varscan2
- ZNF221 | c.284A>T p.Q95L | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as COSV99240652; called by muse, mutect2
- ZNF320 | c.1041T>A p.H347Q | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101206851; called by muse, mutect2, varscan2
- ZNF582 | c.437A>T p.H146L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV100018612; called by muse, mutect2, varscan2
- ZNF8 | c.1004A>T p.H335L | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99544210; called by muse, mutect2
- ZSWIM2 | c.90C>G p.S30R | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV99720074; called by muse, mutect2, varscan2
- ACACA | c.1717A>G p.N573D | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ACLY | c.632dup p.V212Sfs*5 | Frame Shift Ins (INS) | VAF 34/95 reads (36%) | called by mutect2, pindel, varscan2
- APP | c.1484del p.K495Rfs*15 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | called by mutect2, pindel, varscan2
- BOP1 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- COQ6 | c.1111_1114del p.V371Ifs*32 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel, varscan2
- EPM2A | c.157del p.A53Pfs*37 | Frame Shift Del (DEL) | VAF 28/133 reads (21%) | called by mutect2, pindel*, varscan2
- HCN4 | c.876del p.T293Hfs*43 | Frame Shift Del (DEL) | VAF 32/154 reads (21%) | called by mutect2, pindel, varscan2
- HGFAC | c.1596_1602dup p.C535Tfs*13 | Frame Shift Ins (INS) | VAF 20/160 reads (13%) | called by mutect2, varscan2
- IGHV5-51 | c.116T>A p.I39N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB10 | c.2025G>T p.E675D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.02); called by muse, mutect2
- PCDHB9 | c.2025G>T p.E675D | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.019); called by muse, mutect2
- PRSS48 | c.237del p.Y79* | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | called by mutect2, pindel, varscan2
- TMC6 | c.561del p.K188Sfs*40 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, varscan2
- TRPV1 | c.2152del p.R718Gfs*31 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | called by mutect2, pindel, varscan2
- TTBK1 | c.3574C>T p.L1192F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2
- TXN2 | c.70del p.W24Gfs*19 | Frame Shift Del (DEL) | VAF 14/83 reads (17%) | called by mutect2, pindel, varscan2
- AATK | c.1881A>T p.A627= (on ENST00000326724 / NM_001080395.3; = p.A524= on NM_004920.2) | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100352680; called by muse, mutect2
- ADAMTS19 | c.2799C>T p.C933= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as rs754348548, COSV50735590; called by muse, mutect2, varscan2
- ADCY8 | c.1752T>C p.T584= | Silent (SNP) | VAF 37/178 reads (21%) | catalogued as COSV53899574, COSV53915819; called by muse, mutect2, varscan2
- ADGRL3 | c.1473T>A p.S491= (on ENST00000506720 / NM_001322402.2; = p.S423= on NM_015236.6) | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs763251045, COSV101546985; called by muse, mutect2, varscan2
- AKAP10 | c.1170C>T p.L390= | Silent (SNP) | VAF 33/371 reads (9%) | catalogued as COSV99855369; called by muse, mutect2
- ALAS2 | c.33C>T p.C11= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV100238164; called by muse, mutect2, varscan2
- APC | c.7731A>T p.S2577= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV99966964; called by muse, mutect2, varscan2
- ATP10A | c.954T>C p.V318= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100791077; called by muse, mutect2, varscan2
- AXDND1 | c.2676T>C p.H892= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV100858306; called by muse, mutect2, varscan2
- B3GALT1 | c.159A>T p.I53= | Silent (SNP) | VAF 38/192 reads (20%) | catalogued as COSV100002623; called by muse, mutect2, varscan2
- BRS3 | c.243T>A p.V81= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as COSV101036528; called by muse, mutect2, varscan2
- C10orf90 | c.1563A>T p.V521= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV99503585; called by muse, mutect2
- CACNA1H | c.4344T>A p.G1448= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV100671806; called by muse, mutect2, varscan2
- CDC37L1 | c.852T>G p.V284= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV101116505; called by muse, mutect2, varscan2
- CHST13 | c.345G>A p.V115= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV100081090; called by muse, mutect2, varscan2
- CLK3 | c.883C>A p.R295= (on ENST00000395066 / NM_001130028.1; = p.R147= on NM_003992.4) | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as rs751508782, COSV100775866, COSV61412327; called by muse, mutect2, varscan2
- CNBD1 | c.1158A>G p.R386= | Silent (SNP) | VAF 30/550 reads (5%) | catalogued as COSV101582185; called by muse, mutect2
- CNTNAP5 | c.777C>G p.T259= | Silent (SNP) | VAF 49/143 reads (34%) | catalogued as COSV101443328; called by muse, mutect2, varscan2
- COL11A2 | c.2178C>T p.D726= (on ENST00000341947 / NM_080680.3; = p.D619= on NM_080679.2) | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as rs138650682; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL12A1 | c.2796T>C p.V932= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV100485741; called by muse, mutect2, varscan2
- CREB3L3 | c.1131A>T p.P377= | Silent (SNP) | VAF 11/170 reads (6%) | called by muse, mutect2
- CTTNBP2 | c.4491T>C p.N1497= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV99353596; called by muse, mutect2, varscan2
- CUL9 | c.2382G>A p.G794= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs775629593, COSV99335173; called by muse, mutect2, varscan2
- CXCR6 | c.567T>A p.T189= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV99945461; called by muse, mutect2, varscan2
- DCLK3 | c.1407C>T p.H469= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as rs747503381, COSV101373941; called by muse, mutect2, varscan2
- DHX32 | c.2055T>A p.S685= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99501527; called by muse, mutect2
- DHX35 | c.2061A>G p.Q687= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99326689; called by muse, mutect2, varscan2
- DMRT2 | c.1020A>G p.R340= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV99425995; called by muse, mutect2
- DNAJB6 | c.273C>T p.F91= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as rs759982570, CM157384, COSV100055504; called by muse, mutect2, varscan2
- E2F7 | c.1347A>T p.A449= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100523435; called by muse, mutect2, varscan2
- EFCAB5 | c.489T>A p.T163= | Silent (SNP) | VAF 31/244 reads (13%) | catalogued as COSV100300062; called by muse, mutect2, varscan2
- EIF2AK1 | c.858A>T p.P286= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as rs1327893323, COSV99551766; called by muse, mutect2, varscan2
- EMC10 | c.669C>T p.F223= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as rs766834639, COSV58543279; called by muse, mutect2, varscan2
- ETHE1 | c.642G>A p.R214= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV52671658; called by muse, mutect2, varscan2
- EXT1 | c.1365A>T p.L455= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as COSV100983861; called by muse, mutect2
- EYA4 | c.105A>T p.L35= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100765573; called by muse, mutect2, varscan2
- FIZ1 | c.114G>C p.L38= | Silent (SNP) | VAF 18/202 reads (9%) | catalogued as COSV99684528; called by muse, mutect2
- FLG | c.7083A>G p.R2361= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV100911408; called by muse, mutect2
- HS3ST4 | c.132T>C p.S44= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100500826; called by muse, mutect2
- IFNA16 | c.102T>C p.N34= | Silent (SNP) | VAF 38/185 reads (21%) | catalogued as rs372911133, COSV101207065; called by muse, mutect2, varscan2
- IGLV9-49 | c.63T>A p.P21= | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2
- IL12RB2 | c.2013T>C p.N671= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99254934; called by muse, mutect2, varscan2
- JAK2 | c.1365A>G p.T455= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV101072253; called by muse, mutect2, varscan2
- KCNH8 | c.2928T>C p.H976= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV100109310; called by muse, mutect2, varscan2
- KIAA1549 | c.4125G>A p.A1375= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as rs377023001; called by muse, mutect2, varscan2
- KIF5C | c.93C>G p.P31= | Silent (SNP) | VAF 79/266 reads (30%) | catalogued as COSV101371335; called by muse, mutect2, varscan2
- KLHL18 | c.909G>T p.L303= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as COSV99230732; called by muse, varscan2
- KRT18 | c.327G>A p.E109= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs1366517311, COSV101183996, COSV66315979; called by muse, mutect2, varscan2
- LAMA1 | c.3255C>T p.P1085= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs375804587; called by muse, mutect2, varscan2
- LHX1 | c.273C>T p.C91= | Silent (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- LMNB1 | c.522A>G p.E174= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV54397959, COSV99745786; called by muse, mutect2
- MCOLN3 | c.1212C>T p.T404= | Silent (SNP) | VAF 79/204 reads (39%) | catalogued as COSV100352675; called by muse, mutect2, varscan2
- MST1R | c.3636G>T p.R1212= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99618376; called by muse, mutect2, varscan2
- MUC17 | c.5322T>C p.I1774= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as COSV100072647; called by muse, mutect2, varscan2
- NEBL | c.396T>A p.A132= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV101008911; called by muse, mutect2, varscan2
- NES | c.3258A>T p.S1086= | Silent (SNP) | VAF 21/313 reads (7%) | catalogued as COSV100957830; called by muse, mutect2
- NPHS2 | c.24C>T p.S8= | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as rs202081233, COSV100858146; called by muse, mutect2, varscan2
- NUP210 | c.3819A>G p.E1273= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV99595971; called by muse, mutect2, varscan2
- OOEP | c.276C>T p.V92= | Silent (SNP) | VAF 62/126 reads (49%) | catalogued as rs372105159; called by muse, mutect2, varscan2
- OR5H1 | c.894A>T p.T298= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs376802329; called by muse, mutect2, varscan2
- PABPC1 | c.99G>C p.P33= | Silent (SNP) | VAF 138/326 reads (42%) | catalogued as COSV100589475; called by muse, mutect2, varscan2
- PAM | c.1554T>C p.A518= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as rs756785296, COSV99173250; called by muse, mutect2, varscan2
- PIH1D1 | c.138A>T p.T46= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV99221059; called by muse, mutect2, varscan2
- PPP1R10 | c.2010A>T p.P670= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100919802; called by muse, varscan2
- PRKAR1A | c.540A>C p.G180= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100675143; called by muse, mutect2, varscan2
- PRKDC | c.888C>G p.V296= | Silent (SNP) | VAF 23/178 reads (13%) | catalogued as COSV100039703; called by muse, mutect2, varscan2
- PTEN | c.942A>G p.E314= | Silent (SNP) | VAF 43/290 reads (15%) | catalogued as COSV100910054, COSV64290700; called by muse, mutect2, varscan2
- PTPRD | c.4146A>T p.P1382= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100644152; called by muse, mutect2, varscan2
- REM1 | c.540G>T p.R180= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV99147025; called by muse, mutect2, varscan2
- RIN2 | c.1194T>A p.P398= (on ENST00000255006 / NM_001242581.1; = p.P349= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 216/1544 reads (14%) | catalogued as COSV99656871; called by muse, varscan2
- RYR2 | c.3270C>T p.A1090= | Silent (SNP) | VAF 51/271 reads (19%) | catalogued as rs1344074824, COSV100769331, COSV100769353; called by muse, mutect2, varscan2
- RYR2 | c.14334A>T p.V4778= | Silent (SNP) | VAF 24/279 reads (9%) | catalogued as COSV100769354; called by muse, mutect2
- SEMA6D | c.2124A>G p.T708= (on ENST00000316364 / NM_153618.2; = p.T646= on NM_020858.2) | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV100316767, COSV60378224; called by muse, mutect2, varscan2
- SLC22A7 | c.1122C>T p.N374= (on ENST00000372585 / NM_153320.2; = p.N372= on NM_006672.3) | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as rs760343501, COSV99240254; called by muse, mutect2, varscan2
- SLC3A2 | c.600C>A p.A200= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs921536046, COSV100101314; called by muse, mutect2, varscan2
- SLITRK1 | c.861A>T p.P287= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV100999892; called by muse, mutect2, varscan2
- SPPL2C | c.2013T>C p.G671= | Silent (SNP) | VAF 2/18 reads (11%) | called by muse, mutect2
- STX5 | c.348A>G p.T116= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV99586838; called by muse, mutect2, varscan2
- TAF1C | c.912C>T p.S304= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs780240179, COSV100499518, COSV100499555; called by muse, mutect2, varscan2
- TCTE1 | c.957T>A p.I319= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV101025376; called by muse, mutect2
- TET2 | c.2592C>T p.H864= | Silent (SNP) | VAF 59/245 reads (24%) | catalogued as COSV99482168; called by muse, mutect2, varscan2
- TFRC | c.1416G>A p.S472= | Silent (SNP) | VAF 157/477 reads (33%) | catalogued as rs776990727, COSV100786431; called by muse, varscan2
- TLCD3A | c.636C>G p.L212= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100021291; called by muse, mutect2
- TLL2 | c.2109C>T p.I703= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as COSV100780226; called by muse, mutect2, varscan2
- TMEM132B | c.3033T>C p.N1011= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV100169162; called by muse, mutect2, varscan2
- TMEM132D | c.3198G>C p.V1066= | Silent (SNP) | VAF 48/151 reads (32%) | catalogued as COSV101242712, COSV67162833; called by muse, mutect2, varscan2
- TMTC3 | c.36A>T p.I12= | Silent (SNP) | VAF 40/205 reads (20%) | catalogued as COSV99898245; called by muse, mutect2, varscan2
- UBALD2 | c.342C>T p.A114= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs1414847626, COSV99429001; called by muse, mutect2, varscan2
- USP26 | c.670T>C p.L224= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV100896599; called by muse, mutect2, varscan2
- USP43 | c.1602G>A p.A534= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as rs764359781, COSV99556546; called by muse, mutect2, varscan2
- VSTM1 | c.561T>C p.D187= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100618751; called by muse, mutect2, varscan2
- WT1 | c.1353C>A p.S451= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV100187700; called by muse, mutect2, varscan2
- XRN2 | c.2634G>A p.Q878= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs1434477125, COSV101018200; called by muse, mutect2, varscan2
- YTHDC1 | c.978A>G p.S326= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100704662; called by muse, mutect2, varscan2
- ZNF124 | c.573T>C p.S191= (on ENST00000543802 / NM_001297568.1; = p.S129= on NM_003431.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/213 reads (7%) | catalogued as COSV100517718; called by muse, mutect2
- ZNF335 | c.468G>A p.E156= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV100532851; called by muse, mutect2
- ZNF491 | c.1032A>T p.I344= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV100021850; called by muse, mutect2, varscan2
- ZNF709 | c.1296C>A p.S432= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV101172147; called by muse, mutect2, varscan2
- ZNF827 | c.2136A>G p.P712= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as COSV101061254; called by muse, varscan2
- ZNF827 | c.2058C>G p.V686= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV101061255; called by muse, varscan2
- ANKRD7 | c.179+2929C>T | Intron (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99501036; called by muse, mutect2, varscan2
- CALCR | c.51+2963G>A | Intron (SNP) | VAF 9/90 reads (10%) | catalogued as COSV64007639; called by muse, mutect2
- CES2 | c.-40G>T | 5'UTR (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100399169; called by muse, mutect2, varscan2
- KANK3 | chr19:8322884 A>C | 3'Flank (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100035503; called by muse, mutect2, varscan2
- KCNAB1 | c.276-129624G>A | Intron (SNP) | VAF 24/213 reads (11%) | catalogued as COSV56757914; called by muse, mutect2, varscan2
- KMT5C | c.*2A>T | 3'UTR (SNP) | VAF 3/50 reads (6%) | catalogued as COSV99726138; called by muse, mutect2
- NDUFA10 | c.547+670G>T | Intron (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99401354; called by muse, mutect2, varscan2
- NRP2 | c.2440+9459A>T | Intron (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99784002; called by muse, mutect2, varscan2
- OR2U1P | n.581A>G | RNA (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- UBAC2 | c.808-11638C>G | Intron (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100854197; called by muse, mutect2, varscan2
